Gene-level copy-number profile of tumor specimen TCGA-A2-A3XS-01A from TCGA case TCGA-A2-A3XS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 63.0 years (23,000 days).
Specimen TCGA-A2-A3XS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b53f403a-449d-4a77-891e-562a0ce6ff75.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A3XS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9a30f45-67b4-4d5f-87da-7af13ba8757e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 2,366; copy number 2: 21,386; copy number 3: 19,671; copy number 4: 10,438; copy number 5: 2,550; copy number 6: 1,885; copy number 7: 78; copy number 8: 1,124; copy number 9: 20; copy number 12: 9; copy number 13: 22; copy number 16: 53; copy number 17: 150; copy number 22: 35; copy number 28: 8; copy number 42: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A3XS-01A-11D-A22W-01): tumor purity 0.43, ploidy 5.2, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,508 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–148,288,951, 47 genes, copy number 16: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,344,638, 6 genes, copy number 16: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr1:149,754,301–153,348,841, 201 genes, copy number 9–22 (broad region; genes not listed).
- chr4:137,943,022–139,045,939, 15 genes, copy number 7 (within-gene range 4–7): AC097511.1, LINC00616, SLC7A11-AS1, SLC7A11, AC093903.1, LINC00498, LINC00499, LINC00500, AC105416.1, AC098859.1, AC098859.2, AC093766.1, AC109927.1, AC109927.2, NOCT.
- chr4:139,055,475–139,055,578, 1 gene, copy number 7: RNU6-531P.
- chr6:133,502,252–133,892,802, 1 gene, copy number 8 (within-gene range 6–8): TARID.
- chr6:133,676,729–135,813,990, 44 genes, copy number 8–42: FTH1P26, LINC01312, TCF21, TBPL1, AL035699.1, SLC2A12, AL449363.1, AL449363.2, HMGA1P7, RN7SL408P, SGK1, RPS29P32, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1.
- chr6:135,854,053–135,888,133, 2 genes, copy number 12: AL360178.1, AL360178.2.
- chr7:7,356,203–8,004,053, 10 genes, copy number 12–28 (within-gene range 3–28): COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1.
- chr8:42,896,946–43,030,535, 1 gene, copy number 13 (within-gene range 2–13): HOOK3.
- chr8:43,018,424–124,372,692, 1,176 genes, copy number 7–13 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 9 (within-gene range 3–9): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 2,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
